Somatic mutation profile of tumor specimen TCGA-A3-3363-01A (aliquot TCGA-A3-3363-01A-01W-0886-08) from TCGA case TCGA-A3-3363, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 50.9 years (18,596 days).
Specimen TCGA-A3-3363-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5f39295-23c4-4071-b323-5158ecc0db1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3363-11A (Solid Tissue Normal), aliquot TCGA-A3-3363-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/115c8432-3dbf-4f36-a8b5-3849b8339c09

The open-access MAF lists 85 somatic variants for this specimen: 70 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 14, Frame Shift Ins 7, Frame Shift Del 5, Nonsense Mutation 3, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.3415C>T p.P1139S | Missense Mutation (SNP) | VAF 326/505 reads (65%) | SIFT tolerated (0.69); PolyPhen benign (0.024); catalogued as COSV61264126; called by muse, mutect2, varscan2
- ADGRF1 | c.2138T>A p.I713K | Missense Mutation (SNP) | VAF 126/244 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51945774; called by muse, varscan2
- AKAP8L | c.1709G>A p.G570E | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.624); catalogued as rs1568258291, COSV54102768; called by muse, mutect2
- ANKRD34A | c.838C>G p.L280V | Missense Mutation (SNP) | VAF 68/136 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60161042; called by muse, mutect2, varscan2
- ANPEP | c.251C>A p.S84Y | Missense Mutation (SNP) | VAF 136/436 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.119); catalogued as COSV55591881, COSV55595757; called by muse, mutect2
- ARID1B | c.3723G>A p.M1241I | Missense Mutation (SNP) | VAF 187/283 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV51663679; called by muse, mutect2, varscan2
- BMP1 | c.1839dup p.N614Qfs*21 | Frame Shift Ins (INS) | VAF 11/76 reads (14%) | catalogued as rs758822270; called by mutect2, varscan2
- BORCS5 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 35/216 reads (16%) | catalogued as COSV53802829; called by muse, mutect2, varscan2
- BSDC1 | c.503C>A p.S168Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs796323784, COSV61982118; called by mutect2, varscan2
- C2CD5 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 161/708 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as rs942658053, COSV61724826; called by muse, mutect2, varscan2
- CACNA1D | c.6447G>C p.E2149D (on ENST00000350061 / NM_001128840.3; = p.E2169D on NM_000720.4) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.986); catalogued as COSV55448819, COSV55464333; called by muse, mutect2, varscan2
- CCDC14 | c.1822A>G p.K608E (on ENST00000488653; = p.K560E on NM_022757.5) | Missense Mutation (SNP) | VAF 21/256 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV59945114; called by muse, mutect2
- CCDC144A | c.245G>A p.G82D | Missense Mutation (SNP) | VAF 40/635 reads (6%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.095); catalogued as COSV61403518; called by muse, mutect2
- CDC14A | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 107/293 reads (37%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.005); catalogued as COSV60558746; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2755C>T p.Q919* | Nonsense Mutation (SNP) | VAF 70/874 reads (8%) | catalogued as rs907913625, COSV62574653; called by muse, mutect2
- CHD3 | c.3303C>A p.Y1101* | Nonsense Mutation (SNP) | VAF 54/1753 reads (3%) | catalogued as COSV57875664; called by muse, mutect2
- CHD8 | c.2978T>C p.F993S (on ENST00000646647 / NM_001170629.2; = p.F714S on NM_020920.4) | Missense Mutation (SNP) | VAF 734/871 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67870715; called by muse, mutect2, varscan2
- CNOT1 | c.2834C>G p.P945R | Missense Mutation (SNP) | VAF 88/334 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); catalogued as COSV55317455; called by muse, mutect2, varscan2
- CUBN | c.2906T>C p.L969P | Missense Mutation (SNP) | VAF 130/399 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV64716825; called by muse, mutect2, varscan2
- DCAF1 | c.2809dup p.Q937Pfs*20 | Frame Shift Ins (INS) | VAF 18/146 reads (12%) | catalogued as rs782606429; called by mutect2, varscan2
- DLG5 | c.4442dup p.A1482Sfs*51 | Frame Shift Ins (INS) | VAF 14/130 reads (11%) | catalogued as rs778796396; called by mutect2, varscan2
- DNAH1 | c.3158T>C p.L1053P | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV70229532; called by muse, mutect2, varscan2
- DNAH7 | c.6976A>G p.I2326V | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.946); catalogued as COSV56767158; called by muse, mutect2, varscan2
- DYRK4 | c.237A>T p.K79N | Missense Mutation (SNP) | VAF 112/199 reads (56%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV50539759; called by muse, mutect2, varscan2
- FAM83E | c.550G>T p.V184F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50031817; called by muse, mutect2
- FDFT1 | c.994C>A p.P332T | Missense Mutation (SNP) | VAF 41/838 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV55042538; called by muse, mutect2
- GCNT4 | c.880dup p.H294Pfs*2 | Frame Shift Ins (INS) | VAF 14/123 reads (11%) | catalogued as rs768450027; called by mutect2, varscan2
- GIT2 | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV58081138; called by muse, mutect2, varscan2
- GOLGA3 | c.665A>C p.K222T | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.744); catalogued as COSV52632701; called by muse, mutect2, varscan2
- GOLIM4 | c.1179G>A p.V393= | Splice Region (SNP) | VAF 84/752 reads (11%) | catalogued as COSV58329941; called by muse, mutect2, varscan2
- GPR155 | c.2353G>T p.D785Y | Missense Mutation (SNP) | VAF 413/713 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55039268; called by muse, mutect2, varscan2
- H4C5 | c.197T>C p.V66A | Missense Mutation (SNP) | VAF 185/326 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV63486752; called by muse, mutect2, varscan2
- IGSF9 | c.3277C>T p.P1093S (on ENST00000368094 / NM_001135050.2; = p.P1077S on NM_020789.4) | Missense Mutation (SNP) | VAF 285/454 reads (63%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.444); catalogued as COSV57422404; called by muse, mutect2, varscan2
- KDM5D | c.800dup p.T268Nfs*7 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | catalogued as rs1461547786; called by pindel, varscan2
- LETM1 | c.432dup p.A145Rfs*61 | Frame Shift Ins (INS) | VAF 26/136 reads (19%) | catalogued as rs745839823; called by mutect2, varscan2
- LMO7 | c.325A>G p.N109D (on ENST00000357063; = p.N124D on NM_005358.5) | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58537883; called by muse, mutect2, varscan2
- LPAR5 | c.772G>C p.G258R | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61692534; called by muse, varscan2
- MPG | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 373/399 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs562548652, COSV54738476; called by muse, mutect2, varscan2
- NCAPD2 | c.2678G>C p.C893S | Missense Mutation (SNP) | VAF 36/275 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as rs149823221; called by muse, mutect2, varscan2
- NUCB2 | c.1040T>C p.L347P | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60375400; called by muse, mutect2, varscan2
- NUP214 | c.4133dup p.V1379Gfs*60 | Frame Shift Ins (INS) | VAF 14/120 reads (12%) | catalogued as rs780417788; called by mutect2, varscan2
- OBSCN | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.837); catalogued as rs758692506, COSV52755492; called by muse, mutect2, varscan2
- PCDHA6 | c.2152T>C p.Y718H | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.91); catalogued as COSV65344467; called by muse, mutect2, varscan2
- PFAS | c.2304G>C p.W768C | Missense Mutation (SNP) | VAF 77/311 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58980678; called by muse, mutect2, varscan2
- PNMA1 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 14/239 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV54095219; called by muse, mutect2
- PRODH2 | c.233T>C p.L78P (on ENST00000301175; = p.L2P on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV56560035; called by muse, mutect2, varscan2
- RBM28 | c.1147T>G p.F383V | Missense Mutation (SNP) | VAF 157/325 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56163291; called by muse, mutect2, varscan2
- RERE | c.3614C>T p.A1205V | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.234); catalogued as rs764364709, COSV61942929; called by muse, mutect2, varscan2
- RHOB | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV55356235; called by muse, mutect2, varscan2
- SCAF8 | c.650C>A p.P217H | Missense Mutation (SNP) | VAF 154/293 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1489934526, COSV65791991; called by muse, mutect2, varscan2
- SCFD2 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66371968; called by muse, mutect2
- SETDB1 | c.2077T>C p.C693R | Missense Mutation (SNP) | VAF 52/344 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54983759; called by muse, mutect2, varscan2
- SLC9A2 | c.1997G>A p.R666Q | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as rs572895281, COSV52131182; called by muse, mutect2, varscan2
- SNX13 | c.2774T>C p.F925S | Missense Mutation (SNP) | VAF 42/61 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101296788; called by muse, mutect2, varscan2
- SRC | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 268/302 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV62440002; called by muse, mutect2, varscan2
- SUSD6 | c.302G>A p.S101N | Missense Mutation (SNP) | VAF 228/266 reads (86%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.947); catalogued as COSV61365540; called by muse, mutect2, varscan2
- TP53I3 | c.131T>C p.L44S | Missense Mutation (SNP) | VAF 95/134 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV53187768; called by muse, mutect2, varscan2
- TRPV5 | c.1746C>A p.H582Q | Missense Mutation (SNP) | VAF 34/1292 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV54686343; called by muse, mutect2
- TWNK | c.1936G>A p.G646R | Missense Mutation (SNP) | VAF 140/598 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.186); catalogued as COSV61327031; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3389G>A p.S1130N | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1221395982, COSV54438023; called by muse, mutect2, varscan2
- USP11 | c.356G>A p.G119E (on ENST00000218348; = p.G76E on NM_001371072.1) | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV54473863; called by muse, mutect2
- VAV2 | c.1538A>G p.N513S (on ENST00000371850 / NM_001134398.2; = p.N503S on NM_003371.4) | Missense Mutation (SNP) | VAF 45/342 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV64082219; called by muse, mutect2, varscan2
- VWA5A | c.1663C>A p.Q555K | Missense Mutation (SNP) | VAF 6/147 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.41); catalogued as COSV64411966, COSV64412945; called by muse, mutect2
- WLS | c.1228A>G p.K410E | Missense Mutation (SNP) | VAF 80/1024 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52042176; called by muse, mutect2
- ARHGAP11A | c.1557del p.M519Ifs*14 | Frame Shift Del (DEL) | VAF 25/79 reads (32%) | called by mutect2, pindel, varscan2
- NAV2 | c.1386_1389del p.S462Rfs*36 (on ENST00000396087 / NM_001244963.2; = p.S439Rfs*36 on NM_145117.5) | Frame Shift Del (DEL) | VAF 36/356 reads (10%) | called by mutect2*, pindel
- NOTCH2 | c.5892C>G p.I1964M | Missense Mutation (SNP) | VAF 68/678 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by mutect2, varscan2
- RANGAP1 | c.1206del p.Q403Rfs*47 | Frame Shift Del (DEL) | VAF 174/537 reads (32%) | called by pindel, varscan2
- TUBB | c.697_704del p.M233Cfs*14 | Frame Shift Del (DEL) | VAF 136/675 reads (20%) | called by mutect2, pindel, varscan2
- ZMIZ1 | c.584del p.P195Qfs*10 | Frame Shift Del (DEL) | VAF 46/387 reads (12%) | called by mutect2, pindel, varscan2
- BCL11A | c.2196C>T p.G732= (on ENST00000335712 / NM_001365609.1; = p.G766= on NM_022893.4) | Silent (SNP) | VAF 10/249 reads (4%) | catalogued as COSV59626823; called by muse, mutect2
- COG8 | c.1365G>A p.V455= | Silent (SNP) | VAF 51/175 reads (29%) | catalogued as COSV54742494; called by muse, mutect2, varscan2
- CREB3 | c.1062A>G p.G354= | Silent (SNP) | VAF 366/1046 reads (35%) | catalogued as COSV59207909; called by muse, mutect2, varscan2
- FREM1 | c.1348C>T p.L450= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as COSV63087342; called by muse, mutect2, varscan2
- GABRA1 | c.66T>A p.T22= | Silent (SNP) | VAF 68/224 reads (30%) | catalogued as COSV50105892; called by muse, mutect2, varscan2
- GLI1 | c.3192C>A p.S1064= | Silent (SNP) | VAF 43/269 reads (16%) | called by mutect2, varscan2
- HK3 | c.531C>T p.D177= | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as COSV52840619; called by muse, mutect2
- KLF11 | c.255G>A p.V85= | Silent (SNP) | VAF 39/249 reads (16%) | catalogued as COSV59940620; called by muse, mutect2, varscan2
- LRRCC1 | c.42G>T p.V14= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV64483597; called by muse, mutect2, varscan2
- PLBD2 | c.1372C>A p.R458= | Silent (SNP) | VAF 53/658 reads (8%) | catalogued as rs756092775, COSV55107036; called by muse, mutect2
- PLCE1 | c.4804C>T p.L1602= | Silent (SNP) | VAF 119/159 reads (75%) | catalogued as COSV53352515; called by muse, mutect2, varscan2
- SLC4A8 | c.1497G>T p.L499= | Silent (SNP) | VAF 100/1516 reads (7%) | catalogued as COSV60653127; called by muse, mutect2
- TMEM214 | c.669C>T p.I223= | Silent (SNP) | VAF 182/550 reads (33%) | catalogued as rs746591790, COSV53192834; called by muse, mutect2, varscan2
- UNC5CL | c.78T>C p.L26= | Silent (SNP) | VAF 342/644 reads (53%) | catalogued as rs750754440, COSV55110170; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.634A>G | RNA (SNP) | VAF 251/568 reads (44%) | called by muse, mutect2, varscan2
